Somatic mutation profile of tumor specimen MBCProject_2741_T1A_WES (aliquot MBCProject_2741_T1A_WES_1) from CMI case MBCProject_2741, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 63.7 years (23,284 days).
Specimen MBCProject_2741_T1A_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2541c2ef-f104-4ca2-a8e0-f8b3cdd00819.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_2741_SALIVA (Saliva), aliquot MBCProject_2741_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da7fc1bd-f900-404f-bde1-092010c0e4d0

The open-access MAF lists 158 somatic variants for this specimen: 91 protein-altering or splice-affecting, 44 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 44, Intron 10, Frame Shift Del 4, 3'UTR 3, Splice Region 3, Nonsense Mutation 3, 5'UTR 3, 5'Flank 3, In Frame Del 2, Splice Site 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 145/224 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTN2 | c.1324C>T p.R442W | Missense Mutation (SNP) | VAF 84/409 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769073315, COSV63978665; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS2 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as rs750197805, COSV51072125; called by muse, mutect2, varscan2
- ADGRV1 | c.6635G>C p.G2212A | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV67982301; called by muse, mutect2, varscan2
- ATP1A2 | c.1139C>A p.T380N | Missense Mutation (SNP) | VAF 199/494 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63403627; called by muse, mutect2, varscan2
- CACNA1H | c.2548C>G p.L850V | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as rs1317099790; called by muse, mutect2, varscan2
- CACNA1H | c.3808G>A p.E1270K | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as rs545971270, COSV61993545; called by muse, mutect2, varscan2
- CCDC82 | c.1362C>G p.F454L | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV53592125; called by muse, mutect2, varscan2
- CD300E | c.359C>G p.S120W | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as rs771231187, COSV60789926; called by mutect2, varscan2
- CFAP61 | c.3605G>C p.R1202T | Missense Mutation (SNP) | VAF 42/526 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV55622884; called by muse, mutect2
- CMYA5 | c.6307G>A p.E2103K | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.371); catalogued as rs560368604, COSV71404525; called by muse, mutect2, varscan2
- CRYBG1 | c.2716G>A p.E906K | Missense Mutation (SNP) | VAF 46/225 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV64811517; called by muse, mutect2, varscan2
- DBN1 | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 30/221 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52788476; called by muse, mutect2, varscan2
- DISP1 | c.11G>C p.S4T | Missense Mutation (SNP) | VAF 27/235 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.115); catalogued as COSV99450203; called by muse, mutect2, varscan2
- DMD | c.2963C>G p.S988C | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV63742571; called by muse, mutect2, varscan2
- DROSHA | c.3505C>T p.H1169Y | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV60772758; called by muse, mutect2, varscan2
- DST | c.15657G>C p.K5219N (on ENST00000361203 / NM_001374722.1; = p.K2807N on NM_015548.5) | Missense Mutation (SNP) | VAF 74/442 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.171); catalogued as COSV55013011; called by muse, mutect2, varscan2
- ERP29 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs1464192555, COSV55674157; called by muse, mutect2, varscan2
- FMN2 | c.1407C>G p.H469Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0.006); catalogued as COSV60447306; called by muse, varscan2
- GABRB3 | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 39/316 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs769077258, COSV54660540; called by muse, mutect2, varscan2
- GINS4 | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52531271; called by muse, mutect2, varscan2
- HMBOX1 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 60/458 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs777042809, COSV55065757; called by muse, mutect2, varscan2
- ITGA4 | c.2128G>C p.D710H | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as rs764498817; called by muse, mutect2, varscan2
- KIAA1614 | c.3032C>T p.S1011L | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV62550626; called by muse, mutect2, varscan2
- KRT73 | c.470A>G p.N157S | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760029002; called by muse, mutect2
- MYH8 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV67964748; called by muse, varscan2
- MYO7B | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs748812090, COSV67347950; called by mutect2, varscan2
- MYOT | c.689G>A p.R230K | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.421); catalogued as COSV99525025; called by muse, mutect2, varscan2
- OGFOD1 | c.1002G>C p.E334D | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.91); catalogued as rs1218028962; called by muse, mutect2
- PAX9 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 49/417 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.074); catalogued as COSV58721264; called by muse, mutect2, varscan2
- PRPF18 | c.513G>A p.A171= | Splice Region (SNP) | VAF 61/359 reads (17%) | catalogued as rs368540337; called by muse, mutect2, varscan2
- RAPGEF2 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 49/245 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.495); catalogued as COSV52425527, COSV52426157; called by muse, mutect2, varscan2
- RAPGEF5 | c.235C>G p.L79V | Missense Mutation (SNP) | VAF 25/258 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as rs918756941; called by muse, mutect2, varscan2
- RELN | c.1901G>A p.R634Q | Missense Mutation (SNP) | VAF 47/354 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs779205093, COSV58986231; ClinVar: uncertain significance; called by muse, varscan2
- RTF1 | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as COSV101048187; called by muse, mutect2
- SORBS1 | c.683C>T p.S228F (on ENST00000361941 / NM_001034954.2; = p.S196F on NM_015385.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.306); catalogued as rs898872895, COSV99527488; called by muse, mutect2, varscan2
- SPATA2L | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); catalogued as rs35017385; called by muse, mutect2, varscan2
- TBC1D10C | c.1273G>A p.G425S | Missense Mutation (SNP) | VAF 49/78 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.156); catalogued as COSV56705885; called by muse, mutect2, varscan2
- TFEB | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1311125282, COSV100026507; called by muse, mutect2, varscan2
- TRA2B | c.856C>A p.R286S | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV52025939; called by muse, mutect2
- USP24 | c.3775G>A p.D1259N | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.135); catalogued as rs761278282, COSV53776408; called by muse, mutect2, varscan2
- VPS8 | c.2206C>T p.R736C (on ENST00000625842 / NM_001349294.1; = p.R734C on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/255 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs781736257, COSV54998419; called by muse, mutect2, varscan2
- WDR44 | c.2300G>A p.R767K | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV54166810; called by muse, mutect2, varscan2
- ZNF275 | c.1171G>A p.G391S | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0.259); catalogued as rs782626018, COSV64705253; called by muse, mutect2, varscan2
- ZNF768 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs1176774306, COSV63320979; called by muse, mutect2
- ZNF99 | c.2069C>A p.S690* | Nonsense Mutation (SNP) | VAF 19/75 reads (25%) | catalogued as COSV101233841, COSV68054546; called by muse, mutect2, varscan2
- ACSM2A | c.786C>G p.D262E (on ENST00000219054; = p.D183E on NM_001308169.2) | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); called by muse, mutect2
- ATP8B2 | c.1131C>T p.V377= (on ENST00000672630; = p.V344= on NM_001005855.2) | Splice Region (SNP) | VAF 42/444 reads (9%) | called by muse, mutect2
- ATRX | c.2750C>A p.S917Y | Missense Mutation (SNP) | VAF 33/215 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- AVIL | c.1262_1276del p.G421_L425del | In Frame Del (DEL) | VAF 29/307 reads (9%) | called by mutect2, pindel
- BRAT1 | c.1672G>T p.E558* | Nonsense Mutation (SNP) | VAF 21/100 reads (21%) | called by muse, mutect2, varscan2
- CACNA1G | c.7096T>C p.S2366P | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CCDC120 | c.1211C>A p.T404N | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CDHR4 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDS2 | c.588+1G>A p.X196_splice | Splice Site (SNP) | VAF 87/227 reads (38%) | called by muse, mutect2, varscan2
- CLPSL1 | c.39_43del p.F14Lfs*66 | Frame Shift Del (DEL) | VAF 112/218 reads (51%) | called by pindel, varscan2
- DLEC1 | c.2155G>A p.V719I | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EIF4EBP1 | c.16A>C p.S6R | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ERBB3 | c.733-5C>A | Splice Region (SNP) | VAF 40/361 reads (11%) | called by muse, mutect2, varscan2
- ERICH6B | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ETS1 | c.85A>T p.N29Y | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FBXO42 | c.917A>G p.N306S | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- FYB2 | c.1168C>A p.P390T | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- GALNT14 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- GPS2 | c.562_568del p.Y188Lfs*155 | Frame Shift Del (DEL) | VAF 30/78 reads (38%) | called by mutect2, pindel, varscan2
- GTF3C2 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 66/360 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- H1-3 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 59/368 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HTR3A | c.867C>G p.I289M | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KCNK7 | c.95_96del p.E32Gfs*10 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | called by mutect2, pindel, varscan2
- LGSN | c.1393G>T p.A465S | Missense Mutation (SNP) | VAF 27/199 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- LRP12 | c.1862T>C p.V621A | Missense Mutation (SNP) | VAF 36/385 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); called by muse, mutect2
- MTF2 | c.1445G>C p.R482T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.01); called by muse, mutect2
- NIT1 | c.592-1G>C p.X198_splice | Splice Site (SNP) | VAF 15/138 reads (11%) | called by muse, mutect2, varscan2
- NRG2 | c.1475C>T p.T492I | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- PAX7 | c.471_495del p.S157Rfs*49 | Frame Shift Del (DEL) | VAF 24/77 reads (31%) | called by mutect2, pindel, varscan2
- PMPCA | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RAD54B | c.2414C>T p.S805L | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- RANBP3 | c.1168G>A p.E390K (on ENST00000340578 / NM_007322.3; = p.E385K on NM_003624.3) | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- RAPGEF3 | c.223C>T p.P75S (on ENST00000389212; = p.P33S on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SIN3A | c.1997G>A p.R666K | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- SLC2A5 | c.1067G>A p.C356Y | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SPTB | c.3526G>A p.D1176N | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- TMEM247 | c.546C>G p.I182M | Missense Mutation (SNP) | VAF 32/251 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMEM94 | c.3271A>T p.K1091* | Nonsense Mutation (SNP) | VAF 105/139 reads (76%) | called by muse, mutect2, varscan2
- TRPM5 | c.1512G>C p.Q504H | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- TTC12 | c.1169T>C p.L390P | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- TTF2 | c.1253_1264del p.T418_L421del | In Frame Del (DEL) | VAF 9/54 reads (17%) | called by mutect2, pindel, varscan2
- TTN | c.7792G>A p.D2598N (on ENST00000591111; = p.D2552N on NM_003319.4) | Missense Mutation (SNP) | VAF 15/98 reads (15%) | PolyPhen benign (0.037); called by muse, mutect2, varscan2
- WASHC2C | c.3277G>A p.E1093K (on ENST00000336378; = p.E1072K on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/421 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- ZNF569 | c.2045G>A p.R682K | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.64); called by muse, varscan2
- ZNF669 | c.815A>G p.H272R | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- AKAP6 | c.2790C>T p.L930= | Silent (SNP) | VAF 30/253 reads (12%) | catalogued as COSV99797986, COSV99803177; called by muse, mutect2, varscan2
- ARSF | c.144C>T p.Y48= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as rs762340304, COSV63839344; called by muse, mutect2, varscan2
- BACH1 | c.66C>G p.L22= | Silent (SNP) | VAF 59/183 reads (32%) | catalogued as rs1028243602; called by muse, mutect2, varscan2
- CACNA1E | c.6588C>A p.T2196= (on ENST00000367573 / NM_001205293.3; = p.T2153= on NM_000721.4) | Silent (SNP) | VAF 20/206 reads (10%) | called by muse, mutect2
- CATSPER2 | c.654C>G p.L218= | Silent (SNP) | VAF 111/213 reads (52%) | called by muse, mutect2, varscan2
- CDC14A | c.816G>A p.G272= | Silent (SNP) | VAF 38/128 reads (30%) | called by muse, mutect2, varscan2
- CSE1L | c.2904G>A p.V968= | Silent (SNP) | VAF 35/251 reads (14%) | called by muse, mutect2, varscan2
- DCAF4L2 | c.213C>T p.S71= | Silent (SNP) | VAF 156/251 reads (62%) | called by muse, mutect2, varscan2
- DCLRE1A | c.1056G>A p.L352= | Silent (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- EHD1 | c.294C>T p.I98= | Silent (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- FMOD | c.801G>A p.A267= | Silent (SNP) | VAF 51/129 reads (40%) | catalogued as rs750163069, COSV61610385; called by muse, mutect2, varscan2
- GMEB2 | c.1440G>A p.L480= | Silent (SNP) | VAF 196/254 reads (77%) | called by muse, mutect2, varscan2
- HDLBP | c.3354G>A p.L1118= | Silent (SNP) | VAF 32/187 reads (17%) | called by muse, mutect2, varscan2
- HIF3A | c.1546C>T p.L516= (on ENST00000377670 / NM_152795.4; = p.L447= on NM_022462.4) | Silent (SNP) | VAF 28/134 reads (21%) | catalogued as rs1230968710; called by muse, mutect2, varscan2
- HS3ST4 | c.969G>T p.L323= | Silent (SNP) | VAF 77/195 reads (39%) | catalogued as COSV100503257; called by muse, mutect2, varscan2
- IGLV7-43 | c.84A>G p.S28= | Silent (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- INA | c.282G>A p.E94= | Silent (SNP) | VAF 44/61 reads (72%) | called by muse, mutect2, varscan2
- MAGEB10 | c.576G>A p.L192= | Silent (SNP) | VAF 18/136 reads (13%) | called by muse, mutect2, varscan2
- MOV10 | c.2490C>T p.I830= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as rs1296850321, COSV53517474; called by muse, mutect2, varscan2
- MTMR11 | c.1143C>T p.L381= (on ENST00000439741 / NM_001145862.2; = p.L309= on NM_181873.3) | Silent (SNP) | VAF 8/115 reads (7%) | called by muse, mutect2
- MYO18A | c.1452G>A p.A484= | Silent (SNP) | VAF 40/287 reads (14%) | catalogued as rs770294431; called by muse, mutect2, varscan2
- NPHP4 | c.1980A>G p.T660= | Silent (SNP) | VAF 37/104 reads (36%) | catalogued as rs201184309; called by muse, mutect2, varscan2
- OCLN | c.1165A>C p.R389= | Silent (SNP) | VAF 111/191 reads (58%) | called by muse, mutect2, varscan2
- PCDHB5 | c.1962C>T p.T654= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as COSV50652418; called by muse, mutect2, varscan2
- PDX1 | c.747G>A p.P249= | Silent (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- PIEZO1 | c.3681C>T p.I1227= | Silent (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2, varscan2
- PODXL2 | c.1530C>T p.A510= | Silent (SNP) | VAF 66/164 reads (40%) | called by muse, mutect2, varscan2
- RBM7 | c.729T>C p.D243= | Silent (SNP) | VAF 25/89 reads (28%) | called by muse, mutect2, varscan2
- SLIT2 | c.4047C>T p.S1349= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as rs1402644304; called by muse, mutect2
- SVEP1 | c.9708C>T p.C3236= | Silent (SNP) | VAF 27/169 reads (16%) | called by muse, mutect2, varscan2
- SYNRG | c.3894C>T p.I1298= | Silent (SNP) | VAF 139/203 reads (68%) | called by muse, mutect2, varscan2
- TBC1D12 | c.795C>T p.G265= | Silent (SNP) | VAF 43/200 reads (22%) | catalogued as rs1351797162; called by muse, mutect2, varscan2
- TCF20 | c.3066G>A p.R1022= | Silent (SNP) | VAF 104/150 reads (69%) | called by muse, mutect2, varscan2
- TDRD6 | c.1149C>T p.D383= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as rs757611177, COSV60175332; called by muse, mutect2, varscan2
- TG | c.3369C>T p.G1123= | Silent (SNP) | VAF 44/460 reads (10%) | called by muse, mutect2, varscan2
- TGM6 | c.648C>T p.Y216= | Silent (SNP) | VAF 59/637 reads (9%) | catalogued as rs140141767, COSV52482855; called by muse, mutect2
- TMEM131 | c.3990C>T p.S1330= | Silent (SNP) | VAF 19/161 reads (12%) | catalogued as COSV51782882; called by muse, mutect2, varscan2
- TMEM200C | c.1242G>T p.P414= | Silent (SNP) | VAF 13/129 reads (10%) | catalogued as COSV67309798; called by muse, mutect2, varscan2
- UNKL | c.762C>T p.H254= | Silent (SNP) | VAF 11/108 reads (10%) | catalogued as rs958360430, COSV57019366; called by muse, mutect2, varscan2
- UTRN | c.4464C>G p.V1488= | Silent (SNP) | VAF 17/101 reads (17%) | called by muse, mutect2, varscan2
- WNK2 | c.4710G>A p.S1570= (on ENST00000297954 / NM_001282394.1; = p.S1533= on NM_006648.3) | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs750204095, COSV52950151; called by muse, mutect2, varscan2
- ZFPM2 | c.1569G>T p.L523= | Silent (SNP) | VAF 46/259 reads (18%) | called by muse, mutect2, varscan2
- ZNF33A | c.1680C>T p.F560= (on ENST00000458705 / NM_006974.3; = p.F561= on NM_006954.2) | Silent (SNP) | VAF 40/391 reads (10%) | called by muse, mutect2, varscan2
- ZNF423 | c.2211C>T p.F737= (on ENST00000563137 / NM_001379286.1; = p.F729= on NM_015069.4) | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs138278000, COSV99283511; called by muse, mutect2, varscan2
- ADAM9 | c.-61G>A | 5'UTR (SNP) | VAF 32/317 reads (10%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824207 G>A | 5'Flank (SNP) | VAF 55/262 reads (21%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499697 del AAG | 5'Flank (DEL) | VAF 98/220 reads (45%) | catalogued as rs1240098525; called by mutect2, pindel, varscan2
- CATSPERD | c.1942-896G>T | Intron (SNP) | VAF 40/113 reads (35%) | called by muse, mutect2, varscan2
- CIB3 | c.-19C>T | 5'UTR (SNP) | VAF 32/115 reads (28%) | called by muse, mutect2, varscan2
- CTBP2 | c.59-2125C>T | Intron (SNP) | VAF 77/199 reads (39%) | called by muse, mutect2, varscan2
- CTCFL | c.1674+762G>A | Intron (SNP) | VAF 14/250 reads (6%) | called by muse, mutect2
- CYP2R1 | c.-14T>G | 5'UTR (SNP) | VAF 46/151 reads (30%) | called by muse, mutect2, varscan2
- DIO3OS | chr14:101552437 G>A | 3'Flank (SNP) | VAF 9/56 reads (16%) | called by muse, varscan2
- KRT40 | c.688-114C>T | Intron (SNP) | VAF 31/129 reads (24%) | called by muse, mutect2, varscan2
- LYPLA2P2 | n.432del | RNA (DEL) | VAF 34/110 reads (31%) | called by mutect2, pindel*, varscan2
- MBD2 | c.542+1660T>C | Intron (SNP) | VAF 14/71 reads (20%) | called by muse, mutect2, varscan2
- MORF4 | n.432G>A | RNA (SNP) | VAF 27/162 reads (17%) | called by muse, mutect2, varscan2
- MTURN | c.162+2301G>C | Intron (SNP) | VAF 40/176 reads (23%) | called by muse, varscan2
- NR4A1 | c.160+3570G>A | Intron (SNP) | VAF 14/87 reads (16%) | called by muse, mutect2, varscan2
- PCNP | c.355-32A>C | Intron (SNP) | VAF 23/166 reads (14%) | catalogued as rs1438823458; called by muse, mutect2, varscan2
- RAD51D | c.*626G>A | 3'UTR (SNP) | VAF 46/341 reads (13%) | catalogued as rs1444205582; called by muse, mutect2, varscan2
- RASAL1 | c.1513-288C>A | Intron (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159517 G>A | 5'Flank (SNP) | VAF 3/23 reads (13%) | catalogued as rs948460302; called by muse, mutect2
- STPG1 | c.*77G>A | 3'UTR (SNP) | VAF 31/133 reads (23%) | called by muse, mutect2, varscan2
- TBX2 | chr17:61412026 C>T | 3'Flank (SNP) | VAF 89/266 reads (33%) | catalogued as rs777618141; called by muse, mutect2, varscan2
- TTC22 | c.1020+466T>G | Intron (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
- ZDHHC20 | c.*1670A>G | 3'UTR (SNP) | VAF 4/22 reads (18%) | catalogued as rs1466649094; called by muse, varscan2
